RC case RC-B5CZ — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8bdb0f1a-1ed6-4352-8965-51d499ff3d21

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1950; Vital status: Alive.

Diagnoses (4)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 67.9 years (24,806 days); Year of diagnosis: 2018; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: Yes; Ann arbor b symptoms described array: Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 194 days; Days to treatment end: 235 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 276 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Other; Initial disease status: Progressive Disease; Days to treatment start: 708 days (1.9 years); Days to treatment end: 708 days (1.9 years); Treatment outcome: Stable Disease; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Other; Initial disease status: Progressive Disease; Days to treatment start: 827 days (2.3 years); Days to treatment end: 827 days (2.3 years); Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 63.2 years (23,070 days); Year of diagnosis: 2013; Days to diagnosis: -1,736 days (-4.8 years); AJCC staging edition: 7th; AJCC pathologic T: T1c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,924 days (-5.3 years); Treatment anatomic sites: Other.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -1,670 days (-4.6 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole; Treatment anatomic sites: Body, total.
3. Synchronous primary of the skin (histology not recorded by GDC). Age at diagnosis: 68.6 years (25,073 days); Year of diagnosis: 2019; Days to diagnosis: 267 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 322 days; Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Recurrence (histology not recorded by GDC). Age at diagnosis: 69.7 years (25,451 days); Days to diagnosis: 645 days (1.8 years).

Follow-up (6 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Days to follow up: 309 days; Disease response: Tumor Free.
- Day 645 (recurrence): Progression or recurrence: Yes; Days to recurrence: 645 days (1.8 years).
- Days to follow up: 847 days (2.3 years); Disease response: Tumor Free.
- Day 1,065 (end of treatment course 1): Disease response: Tumor Free.
- Days to follow up: 1,268 days (3.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase 304 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Positive [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Epstein-Barr Virus.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypothyroidism / Osteoporosis or Osteopenia.
- Timepoint category: Follow-up; Comorbidities: Hypothyroidism / Osteoporosis or Osteopenia.
- Timepoint category: Initial Diagnosis; Weight: 74.8 kg; Height: 162.6 cm; BMI: 28.3.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1985.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5CZ-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5CZ-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
  Slide RC-B5CZ-TBP1-A-1-0-CS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 90; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 95; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
